Somatic mutation profile of tumor specimen TARGET-30-PARYXW-01A (aliquot TARGET-30-PARYXW-01A-01D) from TARGET case TARGET-30-PARYXW, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 6.0 years (2,208 days).
Specimen TARGET-30-PARYXW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f0b15c9-5a27-423d-b002-186bc5257413.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARYXW-10A (Blood Derived Normal), aliquot TARGET-30-PARYXW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f439c44c-4d8e-4ba0-9c88-ea9902d21d8c

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 13, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADARB2 | c.2053C>T p.R685W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.892); catalogued as rs763573681; called by mutect2, varscan2
- DEF6 | c.974T>A p.L325Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57355512; called by muse, mutect2
- PLA2G4F | c.726C>A p.S242R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51829639; called by muse, mutect2, varscan2
- VARS1 | c.1185G>T p.K395N | Missense Mutation (SNP) | VAF 64/285 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs1445255263, COSV65155836; called by muse, mutect2, varscan2
- ZFP37 | c.1360A>G p.I454V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as COSV65288839; called by muse, mutect2, varscan2
- ZSCAN18 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.09); catalogued as rs762993356, COSV53737617; called by muse, mutect2, varscan2
- ABCA9 | c.3448T>C p.S1150P | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- ASCC3 | c.2254C>G p.Q752E | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1532C>G p.T511S | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); called by muse, mutect2
- CNBD2 | c.1674G>T p.L558F (on ENST00000373973 / NM_001365709.1; = p.L554F on NM_080834.4) | Missense Mutation (SNP) | VAF 16/349 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAP3K12 | c.665G>C p.G222A | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.18); called by muse, mutect2
- RAF1 | c.509A>C p.Y170S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERTAD4 | c.938A>C p.Q313P | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2
- AGXT2 | c.1392C>T p.C464= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as COSV51491047; called by muse, varscan2
- GBF1 | c.1071G>T p.V357= (on ENST00000369983 / NM_001377137.1; = p.V356= on NM_004193.3) | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV64149251; called by muse, mutect2, varscan2
- HOXA1 | c.258G>T p.L86= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV56067858; called by muse, mutect2, varscan2
- KIR2DL1 | c.420G>T p.L140= | Silent (SNP) | VAF 12/203 reads (6%) | called by muse, mutect2
- PCDHGA12 | c.54C>T p.I18= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV52755861; called by muse, mutect2
- VANGL2 | c.501C>T p.F167= | Silent (SNP) | VAF 15/156 reads (10%) | catalogued as rs1489659764; called by muse, mutect2, varscan2
